Somatic mutation profile of tumor specimen TCGA-69-7974-01A (aliquot TCGA-69-7974-01A-11D-2184-08) from TCGA case TCGA-69-7974, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.8 years (20,021 days).
Specimen TCGA-69-7974-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37c8101a-899f-401e-9d7d-3269e3658254.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7974-10A (Blood Derived Normal), aliquot TCGA-69-7974-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3b204a6-1be9-457b-826d-e5ee282829d8

The open-access MAF lists 544 somatic variants for this specimen: 422 protein-altering or splice-affecting, 109 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 109, Nonsense Mutation 30, Splice Site 10, Frame Shift Del 10, Intron 7, Frame Shift Ins 3, 5'Flank 2, 3'UTR 2, 3'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 48/94 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882028, CM134054, COSV52820679; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.2892G>C p.E964D | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.844); catalogued as COSV55602355; called by mutect2, varscan2
- ABCC11 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV62326128; called by muse, mutect2, varscan2
- AC098582.1 | c.1643G>C p.W548S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99985382; called by muse, mutect2, varscan2
- ACSL3 | c.1655A>C p.E552A | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV62484928; called by muse, mutect2, varscan2
- ACSM2B | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV61660189; called by muse, mutect2, varscan2
- ADAM23 | c.969C>A p.N323K | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.239); catalogued as COSV52231638; called by muse, mutect2
- ADAMTS15 | c.2356G>T p.V786L | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV54510129; called by muse, mutect2, varscan2
- ADAMTS19 | c.987A>T p.Q329H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV50757842, COSV50804001; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1244C>A p.S415Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV55008355, COSV99647453; called by mutect2, varscan2
- ADGRE1 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV51681337; called by muse, mutect2, varscan2
- ADH1C | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV72463687; called by muse, mutect2
- AEBP1 | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs1392674917, COSV56261606; called by muse, mutect2
- AGO3 | c.2038-2A>T p.X680_splice | Splice Site (SNP) | VAF 3/30 reads (10%) | catalogued as COSV55797517; called by muse, mutect2
- AHNAK | c.6991G>C p.D2331H | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57232521; called by muse, mutect2, varscan2
- AHNAK | c.4724A>C p.Q1575P | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV57232537; called by muse, mutect2, varscan2
- AIFM1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV54858013; called by muse, mutect2, varscan2
- AJAP1 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV65454930; called by muse, mutect2, varscan2
- AKAP11 | c.299G>C p.C100S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV50297972, COSV50303578; called by muse, mutect2, varscan2
- AKNA | c.1952G>T p.C651F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV56315224; called by muse, mutect2
- ALG13 | c.2623A>T p.S875C | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV52643466, COSV52645400; called by muse, mutect2, varscan2
- ALPK2 | c.3932G>T p.R1311I | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV64497650, COSV99077336; called by muse, mutect2, varscan2
- AMER1 | c.1302C>A p.H434Q | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV57664572; called by muse, mutect2, varscan2
- AMOTL1 | c.1255C>A p.Q419K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV100504238; called by muse, mutect2, varscan2
- ANKRD17 | c.7171C>A p.Q2391K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.169); catalogued as COSV58228482; called by muse, mutect2, varscan2
- ANKRD44 | c.2582A>C p.H861P | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV56567113; called by muse, mutect2, varscan2
- ANKRD44 | c.2136G>T p.M712I | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV99984358; called by muse, mutect2, varscan2
- ANO8 | c.2218_2220del p.K740del | In Frame Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs750689373; called by pindel, varscan2
- ANXA5 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV56640341; called by muse, mutect2, varscan2
- AOC1 | c.957C>G p.Y319* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as rs565010501, COSV62870648, COSV62871134; called by muse, mutect2, varscan2
- ARHGAP6 | c.2333C>A p.P778Q (on ENST00000337414 / NM_013427.3; = p.P575Q on NM_013423.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100272498; called by muse, varscan2
- ARMCX5-GPRASP2 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV63439193; called by muse, mutect2, varscan2
- ARNT2 | c.1574G>C p.G525A | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV57590915; called by muse, mutect2, varscan2
- ARSH | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV101139827, COSV66963896; called by muse, mutect2, varscan2
- ATP2A3 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV59227387, COSV59235648; called by muse, mutect2, varscan2
- ATP4A | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 115/566 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.212); catalogued as COSV52872233; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.443); catalogued as rs575815633, COSV52878284; called by muse, mutect2, varscan2
- ATRNL1 | c.3011A>G p.Y1004C | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV58116991; called by muse, mutect2, varscan2
- ATXN2L | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs767436806, COSV57379796; called by muse, mutect2, varscan2
- AUTS2 | c.2596C>G p.L866V | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as COSV61432064; called by muse, mutect2
- AZIN2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs746194223, COSV53860936; called by muse, mutect2, varscan2
- B4GALT5 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV65495401; called by muse, mutect2, varscan2
- BCORL1 | c.3136C>A p.L1046M | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54408444; called by muse, mutect2, varscan2
- BNC2 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV66158296; called by muse, mutect2
- BRINP1 | c.1953G>C p.K651N | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56314324; called by muse, mutect2, varscan2
- BRINP2 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.967); catalogued as COSV64180584; called by muse, mutect2, varscan2
- C2CD3 | c.2020C>T p.L674F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV58101776; called by muse, mutect2, varscan2
- CABS1 | c.1004A>T p.E335V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1440748833, COSV56734696; called by muse, mutect2, varscan2
- CACNA1G | c.3200G>T p.R1067L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61740615; called by muse, varscan2
- CALHM1 | c.506G>T p.W169L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV61708482; called by muse, mutect2, varscan2
- CAPN6 | c.1816C>G p.R606G | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60697451; called by muse, mutect2, varscan2
- CBY2 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.949); catalogued as COSV60120045; called by muse, mutect2
- CCAR1 | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56275083; called by muse, mutect2, varscan2
- CCIN | c.1366G>T p.V456F | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV58725807; called by muse, mutect2
- CD101 | c.29T>A p.F10Y | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV56721504; called by muse, mutect2, varscan2
- CDC42BPA | c.4046G>T p.R1349L (on ENST00000334218 / NM_001366019.2; = p.R1336L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.143); catalogued as COSV62005113, COSV62022978; called by muse, varscan2
- CDH12 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV66451897; called by muse, mutect2, varscan2
- CEP162 | c.908T>A p.L303* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV57625083; called by muse, mutect2
- CEP57 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV57690739; called by muse, mutect2, varscan2
- CES1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs563293177, COSV100828653, COSV62086839; called by muse, mutect2, varscan2
- CFH | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV62778926; called by muse, mutect2, varscan2
- CFH | c.1182G>T p.L394F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV62778930; called by muse, varscan2
- CFHR2 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV66381253, COSV66382351; called by muse, mutect2, varscan2
- CHL1 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.046); catalogued as COSV99850424; called by muse, mutect2, varscan2
- CHRD | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1397511453, COSV52612858; called by muse, mutect2
- CHRM2 | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57785573; called by muse, mutect2, varscan2
- CHRNB2 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV63809553; called by muse, mutect2, varscan2
- CKAP2 | c.1324G>A p.D442N (on ENST00000378037 / NM_001098525.2; = p.D441N on NM_018204.5) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV51624825; called by muse, mutect2, varscan2
- CLCA1 | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52331736; called by muse, mutect2, varscan2
- CLRN1 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV58997307; called by muse, mutect2, varscan2
- CLSPN | c.2764C>G p.Q922E | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV52049865, COSV52057603; called by muse, mutect2
- CNTN6 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63191239; called by muse, mutect2, varscan2
- CNTNAP2 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV62142627, COSV62264874; called by muse, mutect2, varscan2
- CNTRL | c.2305A>T p.S769C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.43); catalogued as COSV53054041; called by muse, mutect2, varscan2
- COL14A1 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52870125; called by muse, mutect2, varscan2
- COL14A1 | c.1351C>A p.L451M | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52870135; called by muse, mutect2, varscan2
- COL5A2 | c.3472-1G>T p.X1158_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV66415865; called by muse, mutect2, varscan2
- CPAMD8 | c.4556G>T p.S1519I (on ENST00000651564; = p.S1472I on NM_015692.5) | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV71597454; called by muse, mutect2, varscan2
- CPZ | c.562C>A p.H188N (on ENST00000360986 / NM_001014447.3; = p.H177N on NM_003652.3) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV59926434; called by muse, mutect2, varscan2
- CSMD3 | c.6547G>T p.G2183C (on ENST00000297405 / NM_001363185.1; = p.G2079C on NM_052900.3) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99827824; called by muse, mutect2
- CSNK1A1L | c.882C>A p.Y294* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV65790340; called by muse, mutect2, varscan2
- CTNNA2 | c.466-1G>A p.X156_splice | Splice Site (SNP) | VAF 8/90 reads (9%) | catalogued as COSV63605051; called by muse, mutect2
- CYBB | c.1678G>T p.G560* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs776358735, CM106298, COSV101059698; called by muse, mutect2, varscan2
- CYP19A1 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53062726; called by muse, mutect2, varscan2
- CYRIA | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV62867158, COSV62867397; called by muse, mutect2, varscan2
- DACH1 | c.1736C>T p.P579L (on ENST00000619232 / NM_001366712.1; = p.P325L on NM_004392.6) | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs577411921, COSV57495890, COSV57515587; called by muse, mutect2, varscan2
- DACT1 | c.569G>T p.S190I | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60023728; called by muse, mutect2, varscan2
- DAGLA | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57200433; called by muse, mutect2, varscan2
- DDX60 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV67099528; called by muse, mutect2, varscan2
- DGKI | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55971180, COSV99932892; called by muse, varscan2
- DHTKD1 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99536150; called by muse, mutect2, varscan2
- DHX30 | c.133G>T p.D45Y (on ENST00000445061 / NM_138615.3; = p.D6Y on NM_014966.3) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100819976; called by muse, mutect2, varscan2
- DLG2 | c.171G>T p.E57D (on ENST00000650630 / NM_001351274.2; = p.E20D on NM_001142699.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs773829830, COSV65878636; called by muse, mutect2, varscan2
- DNASE2B | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1359696029, COSV65738071; called by muse, mutect2, varscan2
- DNTT | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64523755; called by muse, mutect2, varscan2
- DOCK2 | c.1918G>T p.V640L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV56990548; called by muse, mutect2, varscan2
- DRD4 | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV51563502; called by muse, mutect2, varscan2
- DRP2 | c.2114C>A p.T705K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV65811999; called by muse, mutect2, varscan2
- DSG3 | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV57129938, COSV99933873; called by muse, mutect2, varscan2
- DUSP9 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1557036054, COSV61438528; called by muse, mutect2, varscan2
- E2F8 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV51466432; called by muse, mutect2, varscan2
- EIF2D | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as rs371055570; called by muse, mutect2, varscan2
- EIF5A2 | c.383A>T p.N128I | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV55543996; called by muse, mutect2, varscan2
- ELP1 | c.2071G>T p.V691L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV65900153; called by muse, mutect2, varscan2
- EPHA3 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV60715972; called by muse, mutect2, varscan2
- EPHA5 | c.1771G>T p.G591C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs539707153, COSV56676927; called by muse, mutect2, varscan2
- EPHB1 | c.1168C>A p.R390S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.588); catalogued as COSV67658326, COSV67661315, COSV67672652; called by muse, mutect2, varscan2
- EPSTI1 | c.865C>A p.L289M (on ENST00000398762 / NM_001330543.2; = p.L278M on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58049239; called by muse, mutect2, varscan2
- EPYC | c.750C>G p.D250E | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV53802401; called by muse, mutect2, varscan2
- ERBB4 | c.623-1G>T p.X208_splice | Splice Site (SNP) | VAF 37/116 reads (32%) | catalogued as COSV53584252; called by muse, mutect2, varscan2
- ERICH3 | c.3650C>A p.A1217E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58619637; called by muse, mutect2, varscan2
- F13A1 | c.1056C>A p.D352E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53568493; called by muse, mutect2, varscan2
- F13A1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as rs763103004, COSV53568505; called by muse, mutect2, varscan2
- F8 | c.6457G>T p.G2153W | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57706812; called by muse, mutect2, varscan2
- FAM102A | c.1078G>T p.A360S (on ENST00000373095 / NM_001035254.3; = p.A218S on NM_203305.2) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100305431; called by muse, mutect2, varscan2
- FAM47C | c.217C>A p.R73S | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.123); catalogued as COSV100792362; called by muse, mutect2, varscan2
- FAM47C | c.635C>G p.P212R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); catalogued as COSV63730751; called by muse, varscan2
- FAM47C | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63730760; called by muse, varscan2
- FAM47C | c.991C>A p.H331N | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.77); catalogued as COSV100792364, COSV100792596; called by muse, mutect2, varscan2
- FAT2 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV55830360; called by muse, mutect2, varscan2
- FAT4 | c.12059A>G p.Q4020R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV58711068; called by muse, mutect2, varscan2
- FBXO7 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.328); catalogued as rs1190819881, COSV56681740; called by muse, mutect2, varscan2
- FEN1 | c.999A>T p.Q333H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57251570; called by muse, mutect2, varscan2
- FER1L5 | c.6103C>T p.P2035S (on ENST00000623019; = p.P1999S on NM_001293083.2) | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV53844290; called by muse, mutect2
- FGD1 | c.704G>T p.S235I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64309757; called by muse, mutect2, varscan2
- FGD1 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV100910878; called by muse, mutect2, varscan2
- FHOD3 | c.3191C>A p.A1064E (on ENST00000359247 / NM_001281739.3; = p.A1081E on NM_025135.5) | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57189836; called by muse, mutect2, varscan2
- FLG | c.4390G>A p.G1464R | Missense Mutation (SNP) | VAF 153/335 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.341); catalogued as COSV100911461, COSV64245283, COSV64250597; called by muse, mutect2, varscan2
- FLG | c.3111C>A p.H1037Q | Missense Mutation (SNP) | VAF 356/877 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV64250602; called by muse, mutect2, varscan2
- FLG | c.1299C>A p.D433E | Missense Mutation (SNP) | VAF 158/371 reads (43%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as rs759739224, COSV64250607; called by muse, mutect2, varscan2
- FLT4 | c.2165C>A p.S722Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99986244; called by muse, mutect2, varscan2
- FNDC1 | c.2397G>T p.R799S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV51948519; called by muse, mutect2, varscan2
- FOXN2 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61320025; called by muse, mutect2, varscan2
- FREM2 | c.8665G>A p.A2889T | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV54854041; called by muse, mutect2, varscan2
- FRMPD4 | c.1937C>A p.P646Q | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as rs769660304, COSV66224153, COSV66225060; called by muse, mutect2, varscan2
- FSCB | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100469764, COSV61217157, COSV61219673; called by muse, mutect2
- FUS | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54218824, COSV54219909; called by muse, mutect2, varscan2
- FUT6 | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 35/156 reads (22%) | catalogued as COSV54608831; called by muse, mutect2, varscan2
- FZD10 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472947; called by muse, mutect2
- GAB3 | c.109C>A p.R37S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65820872; called by muse, mutect2, varscan2
- GGH | c.911A>T p.Y304F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs1177944061, COSV52652250; called by muse, mutect2, varscan2
- GJA10 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs755945621, COSV65355734; called by muse, mutect2, varscan2
- GK | c.1033A>C p.I345L (on ENST00000427190 / NM_001205019.2; = p.I339L on NM_000167.6) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV66732601; called by muse, mutect2, varscan2
- GLB1L2 | c.230A>C p.Y77S | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV60280858; called by muse, mutect2, varscan2
- GLIS3 | c.2182G>T p.G728C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60932449; called by muse, mutect2, varscan2
- GNA11 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV50019940, COSV50054865; called by muse, mutect2, varscan2
- GPC3 | c.795C>G p.C265W | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63672674; called by muse, mutect2, varscan2
- GPR50 | c.1550C>A p.T517N | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV54443192; called by muse, mutect2, varscan2
- GPR50 | c.1822G>T p.V608F | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV54443208; called by muse, mutect2
- GPR63 | c.187A>T p.S63C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV57743874; called by muse, mutect2, varscan2
- GRIK3 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV66147632; called by muse, mutect2
- GRIN3A | c.555C>G p.C185W | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62458778; called by muse, mutect2, varscan2
- GRM6 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV51450138; called by muse, mutect2, varscan2
- GRM7 | c.842G>T p.R281M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100735902; called by muse, mutect2, varscan2
- GRM7 | c.843G>T p.R281S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100735903; called by muse, mutect2, varscan2
- GRM7 | c.994G>C p.G332R | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735904; called by muse, mutect2, varscan2
- GRM7 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735906; called by muse, mutect2, varscan2
- GSR | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55323476; called by muse, mutect2, varscan2
- GTF3C1 | c.849+1G>T p.X283_splice | Splice Site (SNP) | VAF 21/75 reads (28%) | catalogued as COSV62241528; called by muse, mutect2, varscan2
- GTPBP1 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV53288117; called by muse, mutect2, varscan2
- H3-3B | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV54667088; called by muse, mutect2
- H3-5 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV61188353; called by muse, mutect2, varscan2
- HDAC5 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs147805310; called by muse, mutect2, varscan2
- HNRNPM | c.1125C>G p.I375M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV57694875; called by muse, mutect2, varscan2
- HOXB13 | c.767C>G p.S256W | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51705119; called by muse, mutect2, varscan2
- HOXC11 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 101/204 reads (50%) | catalogued as COSV54534168; called by muse, mutect2, varscan2
- HOXD10 | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1169059904, COSV50905944; called by muse, mutect2, varscan2
- HTATSF1 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV54481804; called by muse, mutect2, varscan2
- IFNL2 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as COSV59594283; called by muse, mutect2, varscan2
- IMPG1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV64062280; called by muse, mutect2, varscan2
- ING1 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.756); catalogued as COSV58172252; called by muse, mutect2
- INTS2 | c.1958A>G p.Y653C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs931031926, COSV52157038; called by muse, mutect2, varscan2
- IPO9 | c.2878G>C p.E960Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.203); catalogued as COSV100843357; called by muse, mutect2, varscan2
- IPO9 | c.2879A>T p.E960V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV100843360; called by muse, mutect2, varscan2
- IQSEC2 | c.3376G>T p.E1126* (on ENST00000642864 / NM_001111125.3; = p.E921* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV64728296; called by muse, mutect2, varscan2
- ITIH6 | c.3869C>A p.A1290D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV54495180; called by muse, mutect2, varscan2
- ITPRID1 | c.2799G>T p.Q933H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV60083778; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1003G>C p.A335P | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV59828769; called by muse, mutect2, varscan2
- KANSL1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 34/466 reads (7%) | catalogued as COSV52274624; called by muse, mutect2
- KCND1 | c.1544G>T p.S515I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.949); catalogued as COSV54416186; called by muse, mutect2, varscan2
- KCNH8 | c.3172G>T p.G1058* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV60478228; called by muse, mutect2, varscan2
- KCNU1 | c.2229T>A p.Y743* | Nonsense Mutation (SNP) | VAF 22/244 reads (9%) | catalogued as COSV67760137; called by muse, mutect2
- KCTD8 | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597483; called by muse, mutect2, varscan2
- KIAA1755 | c.2983C>G p.Q995E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV54081170; called by muse, mutect2, varscan2
- KIF14 | c.2384A>T p.Q795L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV66264309; called by muse, mutect2, varscan2
- KIF21A | c.2069G>T p.R690L (on ENST00000361418 / NM_001378440.1; = p.R677L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV62778618; called by muse, mutect2, varscan2
- KLHL13 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.44); catalogued as COSV53253649; called by muse, mutect2, varscan2
- KNL1 | c.6892C>G p.Q2298E (on ENST00000346991 / NM_170589.5; = p.Q2272E on NM_144508.5) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV100706349, COSV61160800; called by muse, mutect2, varscan2
- KRT1 | c.1449G>T p.R483S | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52869539; called by muse, mutect2, varscan2
- KRTAP11-1 | c.38G>T p.R13M | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60095540; called by muse, mutect2, varscan2
- KRTAP3-2 | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as COSV66957328; called by muse, mutect2
- KRTAP3-3 | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV66956852; called by muse, mutect2
- KYNU | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV51592359; called by muse, mutect2, varscan2
- KYNU | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | catalogued as COSV51582663; called by muse, mutect2, varscan2
- LAMB1 | c.1931G>C p.G644A | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV55970736; called by muse, mutect2, varscan2
- LARP7 | c.275G>T p.R92I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60522414; called by muse, mutect2, varscan2
- LCP1 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV59943540; called by muse, mutect2, varscan2
- LCP2 | c.1517G>T p.R506M | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV50469362; called by muse, mutect2, varscan2
- LPA | c.5564G>A p.W1855* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV60313548; called by muse, mutect2, varscan2
- LRP1B | c.13603C>A p.H4535N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV67279085; called by muse, mutect2, varscan2
- LRRC23 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV50396898; called by muse, mutect2, varscan2
- LRRC4C | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs760514279, COSV53438953, COSV99537469; called by muse, mutect2, varscan2
- LRRC7 | c.501-1G>T p.X167_splice (on ENST00000651989 / NM_001370785.2; = p.X134_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/81 reads (28%) | catalogued as COSV50598705, COSV50641318; called by muse, mutect2, varscan2
- LRRC7 | c.3917C>A p.A1306E (on ENST00000651989 / NM_001370785.2; = p.A1273E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV50641484; called by muse, mutect2, varscan2
- MACF1 | c.2457del p.S820Afs*39 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | catalogued as COSV58373945; called by mutect2, pindel, varscan2
- MAOA | c.1150C>A p.Q384K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV58645573; called by muse, mutect2, varscan2
- MAP4K1 | c.1232C>A p.P411H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.498); catalogued as COSV67713469; called by muse, mutect2, varscan2
- MAPK10 | c.940G>A p.D314N (on ENST00000359221 / NM_001351625.2; = p.D352N on NM_002753.5) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs762664125, COSV60381470; called by muse, mutect2, varscan2
- MARCHF4 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56108928; called by muse, mutect2, varscan2
- MCF2 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.408); catalogued as COSV58495898; called by muse, mutect2, varscan2
- MCOLN2 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52300012; called by muse, mutect2, varscan2
- MDGA2 | c.2198C>T p.A733V (on ENST00000399232 / NM_001113498.2; = p.A435V on NM_182830.4) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV100636535; called by muse, mutect2, varscan2
- MDGA2 | c.2197G>A p.A733T (on ENST00000399232 / NM_001113498.2; = p.A435T on NM_182830.4) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs755779884, COSV100636537; called by muse, mutect2, varscan2
- MED12L | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as rs368991764; called by muse, mutect2, varscan2
- METTL22 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs767535258, COSV50838906; called by muse, mutect2, varscan2
- MGA | c.3127C>T p.R1043* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV54949521; called by muse, mutect2, varscan2
- MGAT3 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs905014537, COSV57864989; called by muse, mutect2, varscan2
- MMP10 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.15); catalogued as COSV54247963, COSV99666489; called by muse, mutect2, varscan2
- MMP17 | c.1388C>G p.P463R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV100861984, COSV62180810, COSV62181530; called by muse, mutect2, varscan2
- MRE11 | c.332A>C p.Y111S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60580825; called by muse, mutect2, varscan2
- MRM1 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs377624988; called by muse, mutect2, varscan2
- MS4A12 | c.279G>C p.V93= | Splice Region (SNP) | VAF 66/318 reads (21%) | catalogued as COSV50014169; called by muse, mutect2, varscan2
- MS4A14 | c.941A>T p.D314V | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV55738629; called by muse, mutect2
- MS4A3 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV53938108; called by muse, mutect2, varscan2
- MST1R | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.312); catalogued as COSV56574449; called by muse, mutect2, varscan2
- MTMR8 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV66396493; called by muse, mutect2, varscan2
- MUC16 | c.26987C>A p.S8996* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as COSV67496862; called by muse, mutect2, varscan2
- MUC16 | c.2012C>G p.S671* | Nonsense Mutation (SNP) | VAF 33/141 reads (23%) | catalogued as COSV67496871; called by muse, mutect2, varscan2
- MUC17 | c.10727C>T p.S3576F | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs374431518, COSV60292618; called by muse, mutect2, varscan2
- MVB12A | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV57680094; called by muse, mutect2, varscan2
- MYH2 | c.1913G>C p.G638A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV55449606; called by muse, mutect2, varscan2
- NALCN | c.4663G>T p.A1555S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV51968102; called by muse, mutect2, varscan2
- NARS2 | c.1165-1G>C p.X389_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | catalogued as COSV55255989; called by muse, mutect2
- NCOA1 | c.1395T>A p.S465R | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56053888; called by muse, mutect2, varscan2
- NEXMIF | c.1983C>A p.H661Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50138448; called by muse, mutect2, varscan2
- NFKB1 | c.961A>G p.I321V (on ENST00000394820 / NM_001382627.1; = p.I322V on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777076983, COSV56956554; called by muse, mutect2, varscan2
- NGF | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149823633; called by muse, mutect2, varscan2
- NIBAN3 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs1226011635, COSV56314258; called by muse, mutect2, varscan2
- NINL | c.2201G>T p.R734M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54009549; called by muse, mutect2, varscan2
- NLGN4X | c.1847C>A p.P616Q | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52038599; called by muse, mutect2, varscan2
- NOP14 | c.2039C>G p.A680G | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.185); catalogued as COSV58628125; called by muse, mutect2, varscan2
- NPFFR2 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58150337, COSV58155063; called by muse, mutect2, varscan2
- NUAK1 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs777522611, COSV54608650; called by muse, mutect2, varscan2
- NUP210 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54414759; called by muse, mutect2, varscan2
- NXF1 | c.1426G>C p.V476L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53672318, COSV53677034; called by mutect2, varscan2
- OAS2 | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60804719; called by muse, mutect2, varscan2
- OGDHL | c.2705G>T p.R902L | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65100677, COSV65104914; called by muse, mutect2, varscan2
- OGDHL | c.1539G>T p.M513I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65104918; called by muse, varscan2
- OR10C1 | c.76G>T p.G26C (on ENST00000622521; = p.G24C on NM_013941.3) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.673); catalogued as COSV101010805, COSV65822915; called by muse, mutect2, varscan2
- OR10C1 | c.887C>A p.T296K (on ENST00000622521; = p.T294K on NM_013941.3) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65824147; called by muse, mutect2, varscan2
- OR10J3 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59955726; called by muse, mutect2, varscan2
- OR13H1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58548726; called by muse, mutect2, varscan2
- OR1L6 | c.799T>A p.S267T (on ENST00000373684; = p.S231T on NM_001004453.2) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV59029817; called by muse, mutect2, varscan2
- OR2Z1 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60692102; called by muse, mutect2, varscan2
- OR4C46 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60219616; called by muse, mutect2, varscan2
- OR4X1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV60723418; called by muse, mutect2, varscan2
- OR5K1 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV60305407; called by muse, mutect2, varscan2
- OR5L1 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs768293269, COSV61735556; called by muse, mutect2, varscan2
- OR7G2 | c.984G>T p.R328S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV59689172; called by muse, mutect2, varscan2
- OR8B4 | c.364T>G p.Y122D | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV62070663; called by muse, mutect2, varscan2
- OTOGL | c.2605A>G p.T869A (on ENST00000547103; = p.T860A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101509039; called by muse, mutect2
- PC | c.1624A>G p.R542G | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58923089; called by muse, mutect2, varscan2
- PCDH10 | c.1489C>A p.Q497K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52104757; called by muse, mutect2, varscan2
- PCDH11X | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53508367; called by muse, mutect2, varscan2
- PCDH15 | c.5814C>A p.N1938K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV57401977; called by muse, mutect2, varscan2
- PCDH8 | c.2185C>A p.R729S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV58815211; called by muse, mutect2
- PCDH8 | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58815220; called by muse, mutect2
- PCDH9 | c.3561C>A p.S1187R (on ENST00000377865 / NM_203487.3; = p.S1153R on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60593868; called by muse, mutect2
- PCDHA2 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.523); catalogued as COSV65371531; called by muse, mutect2, varscan2
- PCDHB12 | c.2078C>G p.A693G | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53396266, COSV53397223, COSV53401445; called by muse, mutect2
- PCDHGA3 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54042350; called by muse, mutect2, varscan2
- PCDHGB1 | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV54042366; called by muse, mutect2, varscan2
- PCDHGB2 | c.2073C>A p.Y691* | Nonsense Mutation (SNP) | VAF 45/136 reads (33%) | catalogued as COSV54042386; called by muse, mutect2, varscan2
- PECR | c.424+1G>T p.X142_splice | Splice Site (SNP) | VAF 17/149 reads (11%) | catalogued as COSV54736034; called by muse, mutect2, varscan2
- PEG3 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV55630692, COSV55649034; called by muse, mutect2, varscan2
- PIWIL4 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as rs144295355; called by muse, mutect2, varscan2
- PLA2G4C | c.1338G>T p.W446C | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.339); catalogued as COSV62788196; called by muse, mutect2, varscan2
- PLCL2 | c.2887G>A p.V963M (on ENST00000615277 / NM_001144382.2; = p.V837M on NM_015184.5) | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV67625755; called by muse, mutect2, varscan2
- PLEKHG5 | c.2411G>T p.G804V (on ENST00000400915 / NM_001042663.3; = p.G767V on NM_020631.6) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV61069793; called by muse, mutect2, varscan2
- PLEKHH3 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV52219879; called by muse, mutect2
- PLEKHS1 | c.357C>A p.D119E (on ENST00000369310 / NM_182601.1; = p.D125E on NM_024889.5) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.619); catalogued as COSV63054541, COSV63056988; called by muse, mutect2, varscan2
- PLPPR4 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV64571182; called by muse, mutect2, varscan2
- PLSCR5 | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV71649278; called by muse, mutect2, varscan2
- PLXNA3 | c.1676C>A p.T559N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV63755890; called by muse, mutect2, varscan2
- PLXNA3 | c.2753G>T p.C918F | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63755894; called by muse, mutect2, varscan2
- PLXNA3 | c.3113G>T p.S1038I | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63755897; called by muse, mutect2, varscan2
- PNPLA6 | c.2494A>T p.S832C (on ENST00000414982 / NM_001166111.2; = p.S784C on NM_006702.5) | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV55385942; called by muse, mutect2, varscan2
- PPFIBP2 | c.1136+1G>C p.X379_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV55082982; called by muse, mutect2, varscan2
- PRKD1 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771413120, COSV59588280; called by muse, mutect2, varscan2
- PRUNE2 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781724534, COSV65048628; called by muse, mutect2, varscan2
- PTCHD1 | c.2357G>T p.W786L | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV65063035; called by muse, mutect2, varscan2
- PTGS1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56295058; called by muse, mutect2, varscan2
- PTPRS | c.3820C>A p.Q1274K | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); catalogued as COSV53639236; called by muse, mutect2, varscan2
- PXDNL | c.2090C>A p.P697Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs374573903, COSV62482449; called by muse, mutect2, varscan2
- PXDNL | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99080570; called by muse, mutect2, varscan2
- RANBP1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52815203; called by muse, mutect2
- RASAL3 | c.1670G>T p.R557I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV59141964; called by muse, mutect2
- RBMS3 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56170775; called by muse, mutect2, varscan2
- RBMXL1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as rs1189512202, COSV53105982; called by muse, varscan2
- RFX1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV54333886; called by muse, mutect2, varscan2
- RHD | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV59647414; called by muse, mutect2, varscan2
- RHD | c.986G>C p.G329A | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV59647425; called by muse, mutect2, varscan2
- RIMS1 | c.4760G>A p.C1587Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV53487266; called by muse, mutect2
- RIMS2 | c.2366C>T p.T789I (on ENST00000666250 / NM_001348490.2; = p.T597I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); catalogued as rs1297862319, COSV51727711; called by muse, mutect2
- ROBO1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759462146, COSV71397243; ClinVar: likely benign; called by muse, mutect2, varscan2
- ROBO2 | c.3829G>C p.A1277P | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as rs757680523, COSV59942113; called by muse, mutect2, varscan2
- RP1L1 | c.6848C>A p.P2283Q | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV66760809; called by muse, mutect2
- RP1L1 | c.6217G>A p.E2073K | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as COSV66760814; called by muse, mutect2, varscan2
- RPS6KA6 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV53127416; called by muse, mutect2, varscan2
- RSBN1 | c.1562G>T p.R521M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54733425; called by muse, mutect2, varscan2
- RYR2 | c.10871A>G p.Y3624C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63717216; called by muse, mutect2, varscan2
- S100Z | c.48C>A p.F16L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100461004, COSV58255567; called by muse, mutect2, varscan2
- SAGE1 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as COSV100186990, COSV61018542; called by muse, mutect2, varscan2
- SAMD4A | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV51888707; called by muse, mutect2, varscan2
- SCN7A | c.2272G>C p.G758R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV69274920; called by muse, mutect2, varscan2
- SDK1 | c.5243A>T p.N1748I | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67390130; called by muse, mutect2, varscan2
- SDK2 | c.6410C>A p.P2137H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.864); catalogued as COSV66197973; called by muse, mutect2, varscan2
- SEC23A | c.1460A>G p.H487R | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs770112771, COSV56979276; called by muse, mutect2, varscan2
- SECISBP2L | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs760749541, COSV55936864, COSV55937635, COSV55938267; called by muse, mutect2, varscan2
- SEMA3E | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57110416; called by muse, varscan2
- SEMA3E | c.999-1G>A p.X333_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57110421; called by muse, varscan2
- SERPINA9 | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs1376792694, COSV54078847; called by muse, mutect2, varscan2
- SERPINB9 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV66234406; called by muse, mutect2, varscan2
- SETBP1 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV56338051; called by muse, mutect2, varscan2
- SHB | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1041686052, COSV66621266; called by muse, mutect2
- SHROOM2 | c.2753G>T p.R918M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101098276; called by muse, mutect2
- SIGLEC7 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58318061; called by muse, mutect2, varscan2
- SIX2 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57392444; called by muse, mutect2, varscan2
- SLC35E3 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60118553; called by muse, mutect2
- SLC38A1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV101284255, COSV67065029; called by muse, mutect2, varscan2
- SLC6A18 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs199799722, COSV57252597; called by muse, mutect2
- SLC6A3 | c.1502T>C p.V501A | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs369821709; called by muse, mutect2
- SLC8A1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60494202, COSV60497847; called by muse, mutect2, varscan2
- SLC9A6 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs587784402, COSV65789120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK2 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59429090; called by muse, mutect2, varscan2
- SLITRK4 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782172412, COSV62026328; called by muse, mutect2, varscan2
- SLK | c.1451A>T p.K484M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV59829402; called by muse, mutect2, varscan2
- SMARCA1 | c.2728C>A p.Q910K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.355); catalogued as COSV64414018; called by muse, mutect2, varscan2
- SMC3 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV62422603; called by muse, mutect2, varscan2
- SNRNP200 | c.5735C>T p.T1912M | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs775059624, COSV55532065; called by muse, mutect2, varscan2
- SNTG1 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.188); catalogued as COSV52475315; called by muse, mutect2, varscan2
- SORCS1 | c.3376G>A p.V1126I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53908568; called by muse, mutect2
- SORCS1 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53859229, COSV53908576; called by muse, mutect2, varscan2
- SORCS3 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63826445; called by muse, mutect2
- SOX10 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100704042, COSV62807568; called by muse, mutect2, varscan2
- SOX7 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as rs773940037, COSV58731840; called by muse, mutect2, varscan2
- SPAG9 | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV56244536; called by muse, mutect2, varscan2
- SRD5A3 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as COSV51713616; called by muse, mutect2, varscan2
- SRPX2 | c.883G>C p.G295R | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884047, COSV65934728; called by muse, mutect2, varscan2
- ST18 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as COSV52511147; called by muse, mutect2, varscan2
- STAM | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV66325998; called by muse, mutect2, varscan2
- STIM2 | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.985); catalogued as COSV52843984; called by muse, mutect2, varscan2
- SYCP2 | c.4178A>T p.Q1393L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV62772936; called by muse, mutect2, varscan2
- SYNE1 | c.3377G>T p.W1126L (on ENST00000367255 / NM_182961.4; = p.W1133L on NM_033071.3) | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54989878, COSV55035915; called by muse, mutect2, varscan2
- TAS1R2 | c.1253G>A p.W418* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100946427, COSV64747452; called by muse, mutect2
- TBX22 | c.1208T>A p.L403* | Nonsense Mutation (SNP) | VAF 86/283 reads (30%) | catalogued as COSV64788061; called by muse, mutect2, varscan2
- TEPP | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV52044562; called by muse, mutect2
- THEG | c.7dup p.D3Gfs*14 | Frame Shift Ins (INS) | VAF 28/101 reads (28%) | catalogued as rs1388876997; called by mutect2, pindel, varscan2
- TIAM1 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54576722; called by muse, mutect2
- TLR4 | c.742C>A p.Q248K (on ENST00000355622 / NM_138554.5; = p.Q208K on NM_003266.4) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV62924362; called by muse, mutect2, varscan2
- TMEFF2 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55841624; called by muse, mutect2
- TMEM131L | c.3845A>G p.Q1282R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs144748311; called by muse, mutect2, varscan2
- TMPRSS15 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53050119; called by muse, mutect2, varscan2
- TMTC4 | c.1304A>G p.H435R (on ENST00000376234 / NM_001350577.2; = p.H454R on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60893740; called by muse, mutect2, varscan2
- TNRC6B | c.4470A>C p.Q1490H (on ENST00000454349 / NM_001162501.2; = p.Q1380H on NM_015088.3) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV57308794; called by muse, mutect2, varscan2
- TRAPPC9 | c.2675G>T p.R892L | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as COSV66910294; called by muse, mutect2
- TRIM49 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV61672052; called by muse, mutect2, varscan2
- TRO | c.1280G>T p.R427M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51508510; called by muse, mutect2, varscan2
- TRPA1 | c.1700T>C p.L567P | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51575117; called by muse, mutect2, varscan2
- TRPS1 | c.973G>C p.D325H (on ENST00000220888 / NM_001330599.2; = p.D338H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55264109; called by muse, mutect2, varscan2
- TTC12 | c.1468G>T p.D490Y | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV59100351; called by muse, mutect2, varscan2
- TTF2 | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV65633833; called by muse, mutect2
- TTN | c.14768G>T p.C4923F (on ENST00000591111; = p.C3996F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | PolyPhen probably damaging (0.997); catalogued as COSV60375036; called by muse, mutect2, varscan2
- TUBA3C | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); catalogued as rs1377606600, COSV67138991; called by muse, mutect2, varscan2
- UNC5C | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); catalogued as COSV71658992; called by muse, mutect2, varscan2
- USH2A | c.11926A>G p.T3976A | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.802); catalogued as COSV56444541; called by muse, mutect2, varscan2
- USP31 | c.3577G>T p.G1193W | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV54857815; called by muse, mutect2, varscan2
- USP31 | c.2590A>T p.R864* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV54857827; called by muse, mutect2, varscan2
- VNN2 | c.1380A>T p.K460N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58474583; called by muse, mutect2, varscan2
- VPS13D | c.10705G>A p.A3569T | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV50693263; called by muse, mutect2, varscan2
- VPS50 | c.1661A>T p.Y554F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV58511704; called by muse, mutect2, varscan2
- WDR13 | c.875C>A p.T292K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54333780; called by muse, mutect2, varscan2
- WNT8A | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as COSV64231822; called by muse, mutect2, varscan2
- WSCD1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV58498718; called by muse, mutect2, varscan2
- ZFHX3 | c.6251C>A p.P2084Q | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV51738103; called by muse, mutect2
- ZHX1 | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52879288; called by muse, mutect2, varscan2
- ZKSCAN3 | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99356803; called by muse, mutect2, varscan2
- ZKSCAN3 | c.941A>C p.H314P | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99356806; called by muse, mutect2, varscan2
- ZNF229 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.297); catalogued as COSV52165516; called by muse, mutect2, varscan2
- ZNF233 | c.1228A>C p.T410P | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV61935036; called by muse, mutect2, varscan2
- ZNF280A | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 32/119 reads (27%) | catalogued as COSV57482565; called by muse, mutect2, varscan2
- ZNF536 | c.880C>A p.R294S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62818001, COSV62835098; called by muse, mutect2, varscan2
- ZNF547 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 27/138 reads (20%) | catalogued as rs994233631, COSV56582323; called by muse, mutect2, varscan2
- ZNF594 | c.2282A>T p.Y761F | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV68386318; called by muse, mutect2
- ZNF622 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 69/474 reads (15%) | catalogued as COSV58073890, COSV58075339; called by muse, mutect2, varscan2
- ZNF662 | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60243258; called by muse, mutect2, varscan2
- ZNF761 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV61889589; called by muse, mutect2, varscan2
- ZNF804A | c.3007C>A p.P1003T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56446586; called by muse, mutect2, varscan2
- ZNF829 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV61743188; called by muse, mutect2, varscan2
- ZNF99 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV68055100, COSV68057039; called by muse, mutect2, varscan2
- ZSCAN18 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as COSV53737448, COSV53737781; called by muse, mutect2, varscan2
- ARID2 | c.482_483del p.L161Cfs*11 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- B2M | c.244_247del p.F82Ifs*20 | Frame Shift Del (DEL) | VAF 40/123 reads (33%) | called by mutect2, pindel, varscan2
- CCDC15 | c.1956del p.R653Efs*31 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- CNTNAP1 | c.423del p.F141Lfs*21 | Frame Shift Del (DEL) | VAF 21/174 reads (12%) | called by mutect2, pindel, varscan2
- CSAG3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2
- GSN | c.1312_1331del p.G438Rfs*48 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel
- IGHV3-66 | c.20G>T p.W7L | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- IGLV2-11 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 49/540 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.331); called by muse, mutect2
- MAGEB6B | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MGA | c.7170del p.A2391Qfs*13 (on ENST00000219905 / NM_001164273.1; = p.A2182Qfs*13 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- MRC1 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLGN4X | c.769del p.A257Pfs*7 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by pindel, varscan2
- P2RY8 | c.147_149delinsAA p.C49* | Nonsense Mutation (DEL) | VAF 17/42 reads (40%) | called by pindel, varscan2*
- PRAMEF8 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RFT1 | c.221dup p.T75Hfs*35 | Frame Shift Ins (INS) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- SPAM1 | c.254_255delinsT p.G85Vfs*18 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by pindel, varscan2*
- ST6GAL2 | c.1520del p.G507Afs*34 | Frame Shift Del (DEL) | VAF 38/126 reads (30%) | called by mutect2, pindel, varscan2
- TBC1D3B | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 105/1352 reads (8%) | called by muse, mutect2
- TRAJ26 | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 40/227 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.52402dup p.V17468Gfs*22 (on ENST00000591111; = p.V10044Gfs*22 on NM_003319.4) | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.2982G>T p.G994= | Silent (SNP) | VAF 62/281 reads (22%) | catalogued as COSV55791628; called by muse, mutect2, varscan2
- ARHGAP33 | c.1488G>T p.S496= | Silent (SNP) | VAF 44/199 reads (22%) | catalogued as COSV50120381, COSV50174570; called by muse, mutect2, varscan2
- ATP4A | c.2136C>T p.I712= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs748500240, COSV52865971, COSV52868425; called by muse, mutect2, varscan2
- ATP8A2 | c.3219G>A p.L1073= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs1304734403, COSV54978175; called by muse, mutect2, varscan2
- BNC2 | c.471C>A p.P157= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV66158307; called by muse, mutect2
- C2orf16 | c.1386G>T p.G462= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV68647368; called by muse, mutect2, varscan2
- CASK | c.1704G>T p.V568= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV59376120; called by muse, mutect2, varscan2
- CASQ1 | c.66G>T p.L22= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV63624604; called by muse, mutect2, varscan2
- CBLN2 | c.231C>G p.A77= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs758434340, COSV54051458, COSV54053241; called by muse, mutect2, varscan2
- CEACAM20 | c.1422C>A p.A474= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV57603461; called by muse, mutect2, varscan2
- CER1 | c.33C>A p.L11= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs545588883, COSV66603791, COSV66604003; called by muse, mutect2, varscan2
- CFAP45 | c.414C>T p.T138= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100928646, COSV63651270; called by muse, mutect2, varscan2
- CHAT | c.1851G>T p.G617= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV60333907; called by muse, mutect2, varscan2
- COL27A1 | c.777C>T p.T259= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV61931124; called by muse, mutect2, varscan2
- CORIN | c.135G>T p.R45= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV56700261; called by muse, mutect2, varscan2
- CYP27C1 | c.1074G>A p.L358= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV58868657; called by muse, mutect2, varscan2
- DCAF12L1 | c.1194A>T p.A398= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV100948139; called by muse, mutect2, varscan2
- DCTN4 | c.573A>T p.P191= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV69783135; called by muse, mutect2, varscan2
- DDX53 | c.1299G>A p.L433= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as COSV60070124; called by muse, mutect2, varscan2
- DGKK | c.2811T>A p.I937= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV65709535; called by muse, mutect2, varscan2
- DHTKD1 | c.1170G>T p.V390= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV99536146; called by muse, mutect2, varscan2
- DOCK10 | c.324G>A p.L108= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV51429007; called by muse, mutect2
- DSG3 | c.819A>G p.S273= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs778722510, COSV99933875; called by muse, mutect2, varscan2
- EEF1AKNMT | c.157C>T p.L53= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs778877134, COSV62283909; called by muse, mutect2, varscan2
- ELAVL3 | c.909G>T p.L303= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV52954381; called by muse, varscan2
- EMILIN1 | c.60G>T p.G20= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV66695510; called by muse, mutect2, varscan2
- EPPK1 | c.4281C>A p.T1427= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as COSV101599821, COSV73262429; called by muse, mutect2, varscan2
- ERN2 | c.2070G>A p.E690= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55623044, COSV55624473; called by muse, mutect2
- FAM47C | c.216C>A p.R72= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV63728427; called by muse, mutect2, varscan2
- FAM47C | c.990C>A p.L330= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV63728156, COSV63731843; called by muse, mutect2, varscan2
- FAT4 | c.13374G>T p.S4458= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as COSV58693915, COSV58711094; called by muse, mutect2
- FCER1A | c.627A>G p.P209= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as COSV63668596; called by muse, mutect2, varscan2
- GABRE | c.1314C>A p.R438= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV64821543; called by muse, mutect2
- GDA | c.828G>C p.V276= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV52998086; called by muse, mutect2, varscan2
- GDF6 | c.225C>A p.P75= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV54628120; called by muse, mutect2, varscan2
- HAUS7 | c.897T>A p.P299= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV57851324; called by muse, mutect2, varscan2
- HDAC6 | c.3636C>T p.P1212= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV57807582; called by muse, mutect2, varscan2
- HK1 | c.18C>T p.L6= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1240941075, COSV53866549; called by muse, mutect2, varscan2
- HK1 | c.159G>A p.R53= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV100065870, COSV53866561; called by muse, mutect2, varscan2
- HTATSF1 | c.258C>A p.T86= | Silent (SNP) | VAF 63/220 reads (29%) | catalogued as COSV54481794; called by muse, mutect2, varscan2
- IL2RA | c.750G>C p.L250= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56923329; called by muse, mutect2, varscan2
- IQGAP1 | c.30G>A p.L10= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV51589226, COSV51591851; called by muse, mutect2, varscan2
- IRS1 | c.3132G>T p.P1044= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV59340641; called by mutect2, varscan2
- IRX4 | c.723C>T p.S241= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV51475220; called by muse, mutect2, varscan2
- ITGAL | c.1074C>T p.L358= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV63324629; called by muse, mutect2, varscan2
- JAK3 | c.3306C>T p.S1102= | Silent (SNP) | VAF 44/209 reads (21%) | catalogued as COSV71687989; called by muse, mutect2, varscan2
- KCNE4 | c.201C>A p.A67= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV56055462; called by muse, mutect2
- KCNK3 | c.1014G>T p.T338= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV57194870; called by muse, mutect2, varscan2
- KIR2DL4 | c.1173G>A p.L391= (on ENST00000396284; = p.L317= on NM_001080770.2) | Silent (SNP) | VAF 47/205 reads (23%) | catalogued as COSV58493155; called by muse, mutect2, varscan2
- KRTAP10-10 | c.603C>G p.T201= | Silent (SNP) | VAF 29/304 reads (10%) | catalogued as COSV59981702; called by muse, mutect2
- KRTAP15-1 | c.93C>T p.P31= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1465652734, COSV61877034, COSV61878180; called by muse, mutect2, varscan2
- LILRA1 | c.996G>A p.P332= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs141507463, COSV99251930; called by muse, mutect2, varscan2
- MAB21L1 | c.360C>A p.S120= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV59826222; called by muse, mutect2, varscan2
- MAGEB6 | c.813C>A p.P271= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as COSV66873205; called by muse, mutect2, varscan2
- MAP2 | c.4965G>C p.A1655= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52305169, COSV52309395; called by muse, mutect2
- MAPT | c.1890C>A p.S630= (on ENST00000262410 / NM_001377265.1; = p.S238= on NM_005910.5) | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV52248295; called by muse, mutect2
- MUC16 | c.16056C>A p.S5352= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1353305238, COSV67469005; called by muse, mutect2, varscan2
- MXRA5 | c.5349C>A p.G1783= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV54231458, COSV54252206; called by muse, mutect2, varscan2
- NCOR2 | c.5682C>T p.V1894= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV62305215; called by muse, mutect2, varscan2
- NLGN4X | c.75C>T p.V25= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV52038617; called by muse, mutect2, varscan2
- NMUR1 | c.1041G>A p.L347= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV59405860; called by muse, mutect2, varscan2
- NOS2 | c.2010C>T p.R670= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs761097099, COSV58227765; called by muse, mutect2, varscan2
- NUTM2G | c.570C>A p.P190= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- NXT2 | c.9G>C p.T3= (on ENST00000372106 / NM_001242617.2; = p.T58= on NM_018698.5) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV54297512; called by muse, mutect2, varscan2
- OLA1 | c.1008A>C p.T336= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52974612; called by muse, mutect2, varscan2
- OPN5 | c.18T>A p.T6= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV55247779; called by muse, mutect2, varscan2
- OR10C1 | c.75G>A p.Q25= (on ENST00000622521; = p.Q23= on NM_013941.3) | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV101010804; called by muse, mutect2, varscan2
- OR10R2 | c.162G>T p.L54= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV63769620; called by muse, mutect2, varscan2
- OR4M1 | c.465T>C p.H155= | Silent (SNP) | VAF 45/274 reads (16%) | catalogued as COSV60063793; called by muse, mutect2, varscan2
- OR52J3 | c.828T>A p.L276= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV66747854; called by muse, mutect2, varscan2
- OR5T2 | c.789C>A p.A263= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV57591125; called by muse, mutect2, varscan2
- OR6M1 | c.939T>G p.T313= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as COSV58435021; called by muse, varscan2
- OR8G2P | c.603C>A p.V201= | Silent (SNP) | VAF 41/183 reads (22%) | called by muse, mutect2, varscan2
- PABPC1L | c.21C>T p.G7= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1412045728, COSV53843358; called by muse, mutect2, varscan2
- PCDHA1 | c.1755G>T p.V585= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as COSV65377189; called by muse, mutect2
- PDGFRA | c.2517G>T p.L839= | Silent (SNP) | VAF 43/243 reads (18%) | catalogued as rs1213039385, COSV57269465; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDZRN3 | c.1803G>A p.A601= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs778163867, COSV55216618; called by muse, mutect2, varscan2
- PLA2G7 | c.1305A>G p.S435= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV51266461; called by muse, mutect2, varscan2
- PLXNB3 | c.2232C>T p.L744= | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as rs1557061678, COSV62802778; called by muse, mutect2, varscan2
- POGLUT2 | c.1062T>C p.I354= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV65683733; called by muse, mutect2, varscan2
- PRPF18 | c.345C>T p.L115= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV60726283; called by muse, mutect2, varscan2
- PTGDR | c.258C>T p.A86= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs780759306, COSV60094536; called by muse, mutect2, varscan2
- RIC3 | c.303A>G p.P101= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs17852023, COSV58305278; called by muse, mutect2, varscan2
- RP1L1 | c.3471G>A p.L1157= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV66760819; called by mutect2, varscan2
- RRAGB | c.415C>A p.R139= (on ENST00000262850 / NM_016656.4; = p.R111= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs769920456, COSV53332041, COSV99469087; called by muse, mutect2, varscan2
- RYR2 | c.2460T>A p.A820= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV63717203; called by muse, mutect2
- SEPTIN6 | c.184C>T p.L62= | Silent (SNP) | VAF 67/596 reads (11%) | catalogued as COSV59717921; called by muse, mutect2, varscan2
- SERPINB7 | c.1002C>A p.T334= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV60535974; called by muse, mutect2, varscan2
- SH3GL2 | c.837C>T p.H279= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV66056160; called by muse, mutect2
- SHANK2 | c.4659G>A p.K1553= | Silent (SNP) | VAF 110/405 reads (27%) | catalogued as COSV53621049; called by muse, mutect2, varscan2
- SLC22A11 | c.210G>C p.L70= | Silent (SNP) | VAF 82/296 reads (28%) | catalogued as COSV57252730, COSV57255223; called by muse, mutect2, varscan2
- SLC35E1 | c.801C>T p.V267= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1325095976, COSV68736710; called by muse, mutect2, varscan2
- SLC5A1 | c.801A>G p.R267= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV56689213; called by muse, mutect2, varscan2
- SMARCA1 | c.1029G>A p.L343= | Silent (SNP) | VAF 101/381 reads (27%) | catalogued as COSV64412746, COSV64413046; called by muse, mutect2, varscan2
- TEP1 | c.36A>T p.P12= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV53001031; called by muse, mutect2, varscan2
- TFB1M | c.99A>G p.L33= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV65700145; called by muse, mutect2, varscan2
- TMEFF2 | c.591T>A p.S197= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV55841631; called by muse, mutect2
- TRPM6 | c.5508T>A p.A1836= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV62523782; called by muse, mutect2, varscan2
- TSPAN17 | c.174G>T p.L58= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as COSV53782138; called by muse, mutect2, varscan2
- TTC7A | c.2475C>A p.A825= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV55415875; called by muse, mutect2, varscan2
- TUBAL3 | c.984G>A p.G328= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs1206389474, COSV66814795; called by muse, mutect2, varscan2
- TXNL1 | c.12G>A p.V4= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV54181293; called by muse, mutect2, varscan2
- UBE2L6 | c.345G>A p.P115= | Silent (SNP) | VAF 39/384 reads (10%) | catalogued as rs774403823, COSV54704018; called by muse, mutect2
- USP38 | c.3051C>T p.N1017= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs779370162, COSV61026592; called by muse, mutect2, varscan2
- VMA21 | c.93G>C p.L31= | Silent (SNP) | VAF 62/274 reads (23%) | catalogued as COSV57757815; called by muse, mutect2, varscan2
- WDR27 | c.591G>T p.V197= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV61216615; called by muse, mutect2, varscan2
- ZEB2 | c.1875C>A p.A625= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs752759296, COSV57967113; called by muse, mutect2, varscan2
- ZNF317 | c.1434C>T p.A478= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1389316847, COSV56111750; called by muse, mutect2, varscan2
- ZNF667 | c.142C>A p.R48= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as COSV52639954; called by muse, mutect2, varscan2
- ABCA2 | chr9:137033073 C>T | 5'Flank (SNP) | VAF 15/117 reads (13%) | catalogued as rs374000413; called by muse, mutect2, varscan2
- ASIC2 | c.556-179782G>T | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99859528; called by muse, mutect2
- B4GALNT1 | c.*1425C>G | 3'UTR (SNP) | VAF 63/114 reads (55%) | catalogued as rs1333942582, COSV57545132; called by muse, mutect2, varscan2
- CCDC33 | c.1291-11549C>A | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99173211; called by muse, mutect2, varscan2
- CFAP61 | c.2503+2300C>A | Intron (SNP) | VAF 33/340 reads (10%) | catalogued as COSV55624878, COSV99843757; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37168983 C>A | 3'Flank (SNP) | VAF 24/123 reads (20%) | catalogued as COSV57075712, COSV57079100; called by muse, mutect2, varscan2
- CTTN | c.*529C>T | 3'UTR (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100097302; called by muse, mutect2, varscan2
- EIF4A2 | c.771+174_771+180dup | Intron (INS) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- MARCHF1 | c.-322-85790C>T | Intron (SNP) | VAF 15/133 reads (11%) | catalogued as rs767799809, COSV72283651, COSV72283998; called by muse, mutect2, varscan2
- PML | c.1710+1132G>T | Intron (SNP) | VAF 49/145 reads (34%) | catalogued as rs766337991, COSV99166751; called by muse, mutect2, varscan2
- SSX6P | n.258A>C | RNA (SNP) | VAF 6/37 reads (16%) | called by muse, varscan2
- TTN | c.10303+1194A>G | Intron (SNP) | VAF 23/193 reads (12%) | catalogued as rs1158438965, COSV60375047; called by muse, mutect2, varscan2
- WNT16 | chr7:121325445 C>A | 5'Flank (SNP) | VAF 21/189 reads (11%) | catalogued as COSV55977895; called by muse, mutect2, varscan2
